Gene-level copy-number profile of tumor specimen ALCH-B3A7-TTP1-A from ALCHEMIST case ALCH-B3A7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 55.9 years (20,402 days).
Specimen ALCH-B3A7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c9a7db7a-4363-474d-9197-99cebe9fe901.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3A7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,294 have no estimate.
https://portal.gdc.cancer.gov/files/28f0869a-1d84-45c9-a310-49d3e87908ba

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 167; copy number 1: 8,757; copy number 2: 43,651; copy number 3: 4,229; copy number 4: 1,148; copy number 5: 153; copy number 6: 13; copy number 7: 40; copy number 8: 164; copy number 9: 2; copy number 11: 1; copy number 23: 1; copy number 29: 2; copy number 46: 1.

Homozygous deletions (total copy number 0; autosomes only): 167 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,331,280–1,335,314, 1 gene (within-gene range 0–1): TAS1R3.
- chr1:11,479,155–11,537,551, 2 genes: DISP3, AL590989.1.
- chr1:12,791,397–12,796,628, 1 gene: PRAMEF1.
- chr4:4,894,182–5,893,086, 10 genes: LDHAP1, RN7SKP113, CYTL1, STK32B, Y_RNA, RN7SKP275, LINC01587, EVC2, EVC, CRMP1.
- chr4:5,923,275–5,923,328, 1 gene: MIR378D1.
- chr4:8,558,725–8,747,727, 3 genes: GPR78, CPZ, AC209005.1.
- chr4:12,639,086–12,641,009, 2 genes: ECM1P2, AC093809.1.
- chr5:57,574,027–57,619,816, 1 gene (within-gene range 0–1): LINCR-0003.
- chr5:72,574,120–72,660,669, 1 gene: LINC02056.
- chr5:73,120,569–73,175,143, 4 genes: TMEM171, AC116345.3, AC116345.2, TMEM174.
- chr5:75,910,283–75,921,660, 3 genes: AC108120.2, BIN2P2, AC108120.1.
- chr5:76,850,001–76,981,158, 3 genes: S100Z, RNU6ATAC36P, CRHBP.
- chr5:90,016,621–90,356,609, 3 genes: MIR3660, LINC01339, AC099554.1.
- chr5:99,522,311–99,525,462, 1 gene: AC114324.1.
- chr5:100,062,275–100,067,954, 1 gene: GUSBP7.
- chr5:100,388,853–100,389,938, 1 gene: AC113385.2.
- chr5:121,040,090–121,060,953, 2 genes: AC008565.1, AC113352.1.
- chr5:135,742,462–135,954,983, 8 genes: AC011431.1, MIR5692C1, AC114296.1, IL9, AC002428.2, AC002428.1, LECT2, FBXL21P.
- chr5:136,212,745–136,521,432, 7 genes: TRPC7, TRPC7-AS1, TRPC7-AS2, AC063980.1, HSPD1P18, HNRNPA1P13, AC112178.1.
- chr5:146,375,591–146,407,359, 2 genes (within-gene range 0–1): AC011396.3, AC011396.1.
- chr5:146,586,099–146,656,695, 2 genes (within-gene range 0–1): RNA5SP196, RN7SL791P.
- chr6:159,353,922–159,401,147, 2 genes: AL357832.1, LINC02529.
- chr12:13,440,884–13,459,776, 2 genes: RNA5SP353, RNU6-590P.
- chr12:131,347,470–131,371,721, 3 genes: LINC02370, AC140118.2, AC140118.1.
- chr13:19,172,773–19,187,618, 3 genes: AL139327.3, TUBA3C, AL139327.1.
- chr13:19,262,797–19,416,188, 7 genes: ANKRD26P3, MRPL3P1, LINC00421, PARP4P2, CCNQP3, AL356259.1, SLC25A15P2.
- chr19:9,087,061–9,236,076, 12 genes: OR1M1, OR7G2, OR7G1, OR7G15P, OR7G3, ZNF317, OR7D2, ELOCP29, OR7E16P, OR7E25P, OR7D4, OR7D1P.
- chr19:15,010,726–15,092,970, 3 genes (within-gene range 0–1): CCDC105, CASP14, OR1I1.
- chr19:22,422,513–22,426,045, 1 gene (within-gene range 0–1): AC011516.1.
- chr19:28,790,812–29,525,752, 16 genes (within-gene range 0–1): MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3.
- chr19:30,219,666–30,957,192, 7 genes: AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1.
- chr19:31,167,457–31,225,143, 1 gene: LINC01791.
- chr19:42,721,638–42,740,481, 1 gene (within-gene range 0–1): PSG3.
- chr19:42,781,206–42,786,595, 1 gene (within-gene range 0–1): CEACAMP6.
- chr19:47,994,632–48,044,079, 2 genes: ELSPBP1, CABP5.
- chr19:54,617,158–54,891,420, 23 genes: LILRB1, LILRB1-AS1, LILRB4, MIR8061, VN1R105P, AC245036.3, AC243962.1, LILRP1, AC245128.2, LILRP2, KIR3DL3, AC245128.1, KIR2DL3, KIR2DP1, KIR2DL1, KIR3DP1, KIR2DL4, KIR3DL1, KIR2DS4, KIR3DL2, RNU6-222P, FCAR, AC245128.3.
- chr19:55,891,699–55,988,629, 2 genes: NLRP13, NLRP8.
- chr19:56,595,313–56,799,602, 1 gene (within-gene range 0–1): ZIM2-AS1.
- chr19:56,669,941–56,848,556, 7 genes (within-gene range 0–1): AC006115.2, OR5AH1P, ZIM2, AC006115.1, PEG3, MIMT1, AC004792.1.
- chr20:56,700,837–56,701,514, 1 gene: PTMAP6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 372 genes in 45 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,600,539–150,629,612, 3 genes, copy number 5: AL356356.1, ENSA, U4.
- chr1:155,148,544–155,227,422, 11 genes, copy number 5: HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1.
- chr1:156,082,573–156,248,117, 8 genes, copy number 5–6: LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6.
- chr1:168,695,874–169,103,276, 1 gene, copy number 5 (within-gene range 3–5): AL135926.1.
- chr1:168,903,905–169,087,005, 1 gene, copy number 5 (within-gene range 4–5): LINC00970.
- chr1:169,059,576–169,062,441, 1 gene, copy number 5: AL031726.2.
- chr1:172,420,685–172,468,831, 1 gene, copy number 5 (within-gene range 3–5): C1orf105.
- chr1:206,634,196–206,684,419, 2 genes, copy number 5: DYRK3-AS1, DYRK3.
- chr1:206,928,522–207,099,993, 6 genes, copy number 6 (within-gene range 3–6): PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB.
- chr1:211,936,249–212,190,259, 8 genes, copy number 5: AC092814.2, INTS7, AC092814.1, DTL, RPL21P28, MIR3122, RN7SKP98, AL606468.1.
- chr4:40,423,267–40,630,875, 1 gene, copy number 5 (within-gene range 4–5): RBM47.
- chr4:40,491,733–40,502,119, 2 genes, copy number 5: AC098869.1, MIR4802.
- chr6:2,851,230–3,021,850, 9 genes, copy number 5: SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1, SERPINB6, LINC01011, NQO2, NQO2-AS1.
- chr6:7,107,597–7,251,980, 4 genes, copy number 7: RREB1, AL355336.1, Y_RNA, AL589644.1.
- chr6:7,540,451–7,586,714, 2 genes, copy number 7: AL031058.1, DSP.
- chr6:11,810,602–11,862,970, 2 genes, copy number 5: AL022724.2, AMD1P4.
- chr6:28,503,296–28,534,955, 2 genes, copy number 5: GPX6, GPX5.
- chr6:30,485,940–30,626,395, 9 genes, copy number 5: RANP1, HLA-E, LINC02569, GNL1, PRR3, ABCF1, MIR877, PPP1R10, MRPS18B.
- chr6:30,696,806–30,955,636, 24 genes, copy number 5–7: RPL7P4, MDC1, MDC1-AS1, TUBB, AL662797.1, FLOT1, Y_RNA, IER3-AS1, IER3, HCG20, RN7SL353P, LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21.
- chr6:32,517,353–32,647,062, 5 genes, copy number 5: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1, HLA-DQA1.
- chr6:32,840,717–32,953,122, 8 genes, copy number 5–6 (within-gene range 4–6): PSMB8, PSMB8-AS1, PSMB9, TAP1, PPP1R2P1, HLA-Z, HLA-DMB, AL645941.2.
- chr6:41,683,978–41,754,109, 3 genes, copy number 5: TFEB, AL035588.1, PGC.
- chr6:42,984,553–43,161,719, 12 genes, copy number 5: PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7.
- chr6:43,671,202–43,786,487, 5 genes, copy number 5 (within-gene range 3–5): MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3.
- chr6:46,852,522–46,954,943, 2 genes, copy number 5: ADGRF5, ADGRF5-AS1.
- chr7:104,940,943–105,014,321, 3 genes, copy number 5 (within-gene range 3–5): AC007384.1, LINC01004, KMT2E-AS1.
- chr9:136,975,092–136,986,410, 3 genes, copy number 6: PTGDS, AL807752.7, LCNL1.
- chr11:565,660–568,457, 2 genes, copy number 5: MIR210HG, MIR210.
- chr11:65,455,258–65,538,704, 9 genes, copy number 5 (within-gene range 3–5): AP000769.1, LINC02736, AP000769.6, MALAT1, AP000769.2, AP000769.5, AP000769.3, SNRPGP19, SCYL1.
- chr11:65,879,837–65,891,635, 3 genes, copy number 5: CTSW, FIBP, CCDC85B.
- chr11:67,483,026–67,491,103, 2 genes, copy number 5: AIP, MIR6752.
- chr15:21,980,277–22,095,857, 8 genes, copy number 5–6 (within-gene range 1–20): OR11J6P, AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2.
- chr15:22,125,511–22,126,434, 1 gene, copy number 9 (within-gene range 5–9): OR4N3P.
- chr15:22,401,208–22,406,944, 1 gene, copy number 23: SPATA31E3P.
- chr15:92,805,770–92,899,701, 3 genes, copy number 5–8 (within-gene range 2–8): AC106028.2, AC106028.4, CHASERR.
- chr17:1,646,145–1,649,866, 1 gene, copy number 6: RILP.
- chr21:10,482,738–20,828,622, 141 genes, copy number 8 (within-gene range 3–8) (broad region; genes not listed).
- chr21:37,593,977–39,529,855, 47 genes, copy number 7–11: AP001407.1, KCNJ6, KCNJ6-AS1, DSCR4, DSCR4-IT1, DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1, LINC01423, ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1, BRWD1-AS2, BRWD1-AS1, HMGN1, Y_RNA, RNF6P1, GET1, GET1-SH3BGR, LCA5L, SH3BGR, MIR6508, MYL6P2, RPS26P4, JCADP1.
- chr21:43,414,483–43,479,534, 4 genes, copy number 9–46: SIK1, LINC00319, LINC00313, AP001048.1.
- chr22:50,523,568–50,551,023, 7 genes, copy number 5: SCO2, U62317.1, TYMP, ODF3B, U62317.3, KLHDC7B-DT, KLHDC7B.

Autosomal genes at a single copy (total copy number 1): 8,757. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
